Somatic mutation profile of tumor specimen TARGET-10-PAPFHX-09A (aliquot TARGET-10-PAPFHX-09A-01D) from TARGET case TARGET-10-PAPFHX, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.4 years (3,439 days).
Specimen TARGET-10-PAPFHX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b91790e-c4d1-48c8-8c01-8a561e8559b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPFHX-14A (Bone Marrow Normal), aliquot TARGET-10-PAPFHX-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ec00ba3-c9ea-469f-8869-d9305efb185f

The open-access MAF lists 24 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, 5'UTR 3, Intron 2, Frame Shift Ins 2, 3'UTR 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.8494C>T p.R2832C | Missense Mutation (SNP) | VAF 63/146 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587779872, CM980159, COSV53732886, COSV53761977; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- JAK2 | c.2047A>G p.R683G | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519721, COSV67572554, COSV67587550; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CPN1 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV64942725; called by muse, mutect2, varscan2
- ETV6 | c.236T>G p.L79* | Nonsense Mutation (SNP) | VAF 40/86 reads (47%) | catalogued as COSV67149104, COSV67151110; called by muse, mutect2, varscan2
- SLC24A5 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs775687860, COSV58317445, COSV58317996; called by muse, mutect2, varscan2
- CNTN4 | c.1033C>A p.P345T | Missense Mutation (SNP) | VAF 91/205 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CTTNBP2 | c.4838T>A p.L1613H | Missense Mutation (SNP) | VAF 63/136 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHV3-64 | c.350dup p.R118Efs*? | Frame Shift Ins (INS) | VAF 14/28 reads (50%) | called by pindel, varscan2
- MUC16 | c.19865C>T p.P6622L | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- NKX6-3 | c.86A>G p.Y29C | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- NPR2 | c.2941G>A p.G981R | Missense Mutation (SNP) | VAF 65/144 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM23 | c.284G>C p.G95A (on ENST00000359890 / NM_001077351.2; = p.G79A on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/204 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RFX2 | c.2044_2045insCC p.L682Pfs*29 | Frame Shift Ins (INS) | VAF 11/62 reads (18%) | called by mutect2, pindel, varscan2
- COL18A1 | c.372C>T p.F124= | Silent (SNP) | VAF 86/257 reads (33%) | catalogued as rs372080967; called by muse, mutect2, varscan2
- PIK3C2G | c.2805T>C p.Y935= (on ENST00000676171; = p.Y894= on NM_004570.5) | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV99853939; called by muse, mutect2, varscan2
- PPL | c.4932C>T p.A1644= | Silent (SNP) | VAF 58/128 reads (45%) | catalogued as rs376932971; called by muse, mutect2, varscan2
- STARD8 | c.2427C>A p.A809= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV99366864; called by muse, mutect2, varscan2
- GRIK2 | c.-82C>T | 5'UTR (SNP) | VAF 18/42 reads (43%) | catalogued as COSV59726041; called by muse, mutect2
- INTS8 | c.-101C>A | 5'UTR (SNP) | VAF 37/83 reads (45%) | catalogued as COSV58250794; called by muse, mutect2, varscan2
- MIR125B1 | n.45G>A | RNA (SNP) | VAF 59/155 reads (38%) | catalogued as rs774745940; called by muse, mutect2, varscan2
- NAP1L1 | c.104-15dup | Intron (INS) | VAF 26/92 reads (28%) | catalogued as rs397839983; called by pindel, varscan2
- NAP1L3 | c.-83C>T | 5'UTR (SNP) | VAF 12/26 reads (46%) | catalogued as rs1569341991, COSV100220322; called by mutect2, varscan2
- PTN | c.*164T>G | 3'UTR (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- SNRPN | c.4-428G>A | Intron (SNP) | VAF 9/151 reads (6%) | catalogued as rs1324565169; called by muse, mutect2
